Surgical pathology report (de-identified scan), TCGA case TCGA-QF-A5YT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site BLN - Baylor, specimen TCGA-QF-A5YT-01A (Primary Tumor).

[page 1 of 4]
Results

SURGICAL PATHOLOGY (Accession

UUID:1CCA2D47-BASD-46A9-89F9-681C58EFC10D

SURGICAL PATHOLOGY

ICD-O-3
Adenocarcinoma, endometrioid NOS
8380/3
Site: Isthmus uteri, lower
uterine segment C54.0
JW 4/16/13

PATHOLOGIC DIAGNOSIS

A. UTERUS WITH CERVIX, TOTAL HYSTERECTOMY:
ENDOMETRIUM:

- ENDOMETRIOID ADENOCARCINOMA
- TUMOR SIZE: 2CM IN GREATEST DIMENSION
- HISTOLOGIC GRADE: FIGO GRADE 1
- MYOMETRIAL INVASION: PRESENT
- INVASION INTO CERVICAL STROMA: PRESENT
- LYMPHOVASCULAR SPACE INVASION: ABSENT
- MARGINS: NEGATIVE FOR MALIGNANCY

MYOMETRIUM:

- ADENOCARCINOMA BY DIRECT EXTENSION
- DEPTH OF INVASION: 10MM
- MYOMETRIAL THICKNESS: 20MM
- 50% MYOMETRIAL INVASION
- ADENOMYOSIS INVOLVED BY ADENOCARCINOMA
- LEIOMYOMATA

SEROSA:

- NO DIAGNOSTIC ALTERATION

CERVIX:

- STROMAL INVASION BY ENDOMETRIOID ADENOCARCINOMA
- TUMOR THICKNESS: 3MM
- TOTAL CERVICAL THICKNESS: 12MM

B. FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:

- NO DIAGNOSTIC ALTERATION

C. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:

- NO DIAGNOSTIC ALTERATION

[page 2 of 4]
PATHOLOGIC STAGING (pTNM / FIGO): II

Primary tumor (pT): pT2

Regional lymph nodes (pN): NX

Distant metastases (pM): MX

Intraoperative Consultation

Intraoperative Frozen Section Diagnosis:

FSA1: Uterus with cervix, hysterectomy:

- Endometrioid carcinoma, FIGO 1 exophytic mass in LUS, no definitive invasion/less than 50%. Fundal endometrium with no gross invasion
- ORG-7 verbally notified at approximately

Staff Pathologist

Pathology Resident

Pertinent Clinical Information

(A) -year-old with endometrial cancer.

(B-C) year-old G0 with FIGO Grade 1 endometrioid endometrial adenocarcinoma.

Gross Description

Specimen Material: A- Uterus, cervix, B- Left tube and ovary, C- Right tube and ovary.

The case is received in three parts each labeled with the patient's name, medical record number and given accession number
and it is accompanied by a requisition form labeled with the same name and same accession number.

Part A: Received fresh labeled "UTERUS, CERVIX" is a 119 gram, 5.5 from cornu to cornu, 6.5 from superior to inferior, and 4.0 from anterior to posterior uterus without adnexa. There is an attached 2.5 x 3 cm cervix with a circular as exuding tan-white, soft tissue/material. The serosa is tan-red, smooth and glistening. The specimen is inked as follows:
Anterior serosa blue
Posterior serosa black and bivalved to reveal a tan-white lush endometrium that measures from 0.3 to 0.9 cm in greatest thickness.

Part A: There is a 2 x 1.5 cm tan-white exophytic mass in the anterior lower uterine segment. The endometrial cavity is sectioned longitudinally to reveal a tan-white, trabeculated myometrium that is 2.5 cm in greatest thickness. Also present is a 0.8 x 0.7 cm intramural, tan-white, whorled

[page 3 of 4]
fibrous nodule and a 0.8 x 0.4 tan-white, whorled fibrous subendometrial nodule located in the fundus. A frozen section is performed and representative sections are submitted as follows in cassettes:

FSA1: representative section of exophytic mass and anterior lower uterine segment

A2-A6: longitudinal full thickness section of the anterior fundus to cervix, area of deepest visible gross invasion

A7-A26: entire endometrium of anterior uterus with anterior cervix

A27: posterior cervix

A28-A45: posterior endometrium in its entirety

A35-A39: longitudinal full thickness section of the fundus to cervix on the side with the visible deepest invasion to include the posterior cervix in cassette 27, to include the subendometrial nodule in cassette 35

A41: endomyometrium to include intramural nodule

Part B: Received in formalin labeled "LEFT TUBE AND OVARY" is a 4.5 cm in length and 0.8 cm in diameter fimbriated fallopian tube with a tan-pink to red-brown hemorrhagic smooth and glistening surface. Attached is a 2.5 x 1.5 x 0.7 cm ovary with a tan-white lobulated surface. The fallopian tube is serially sectioned to reveal a pinpoint to stellate lumen. The ovary is serially sectioned to reveal a 0.2 x 0.1 x 0.1 cm unilocular cyst. The remaining ovarian parenchyma is tan-white- to pink, variegated and smooth.

Representative sections are submitted as follows:

B1: representative sections of fallopian tube

B2-B3: representative sections of ovary

Part C: Received in formalin labeled "RIGHT TUBE AND OVARY" is a 4.8 cm in length and 0.6 cm in diameter tortuous fimbriated fallopian tube with a surface that is tan-pink to red-brown and hemorrhagic. Attached is a 2.3 x 1.5 x 0.5 cm previously disrupted ovary with a tan-white lobulated surface. The fallopian tube is serially sectioned to reveal a pinpoint to stellate lumen. The ovary is serially sectioned to reveal few corpora albicantia and a tan-yellow to tan-pink variegated smooth surface.

Representative sections are submitted as follows:

C1: representative sections of fallopian tube

C2: representative sections of ovary

[page 4 of 4]
Microscopy performed.

Electronically Signed Out

Staff Pathologist

Source: NCI Genomic Data Commons file f97d3964-5c66-41de-b60b-0217f011a21c (TCGA-QF-A5YT.1CCA2D47-BA5D-46A9-89F9-681C58EFC10D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).